Somatic mutation profile of tumor specimen 0E1O0I from CCDI case PBCWRE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male.
Specimen 0E1O0I: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c1077105-0c8f-4d1b-930a-a39d72090f27.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E1NYU (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c348b80e-7359-4b73-807e-9afd9538e148

The open-access MAF lists 53 somatic variants for this specimen: 38 protein-altering or splice-affecting, 5 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Frame Shift Del 12, 3'UTR 5, Silent 5, In Frame Del 5, Intron 3, Nonsense Mutation 3, 5'UTR 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.6852_6855del p.Y2285Tfs*5 (on ENST00000358273 / NM_001042492.3; = p.Y2264Tfs*5 on NM_000267.3) | Frame Shift Del (DEL) | VAF 136/167 reads (81%) | catalogued as rs1555535032; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- PTEN | c.17_18del p.K6Rfs*4 | Frame Shift Del (DEL) | VAF 71/377 reads (19%) | catalogued as rs121913290; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PTEN | c.97_99del p.I33del | In Frame Del (DEL) | VAF 28/162 reads (17%) | catalogued as rs1554893765; ClinVar: uncertain significance / likely pathogenic; called by pindel, varscan2
- ADAMTS3 | c.829G>A p.V277I | Missense Mutation (SNP) | VAF 57/222 reads (26%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.96); catalogued as rs200255750, COSV54387223; called by muse, mutect2, varscan2
- AK7 | c.805G>A p.V269M | Missense Mutation (SNP) | VAF 265/329 reads (81%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs202192874, COSV50881195; called by muse, mutect2, varscan2
- MPO | c.403C>T p.R135* | Nonsense Mutation (SNP) | VAF 304/400 reads (76%) | catalogued as rs181494077, COSV56563853; called by muse, mutect2, varscan2
- PAPLN | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 36/202 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as rs1316107259, COSV53720882; called by muse, mutect2, varscan2
- SDR42E1 | c.1024G>C p.D342H | Missense Mutation (SNP) | VAF 19/453 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.823); catalogued as rs1388640402; called by muse, mutect2
- SOAT1 | c.1315T>G p.F439V | Missense Mutation (SNP) | VAF 15/259 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1490834779; called by muse, mutect2
- VPS37D | c.683C>T p.S228F | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs1455226645; called by mutect2, varscan2
- VPS39 | c.1363_1365del p.K455del (on ENST00000348544 / NM_001301138.2; = p.K444del on NM_015289.5) | In Frame Del (DEL) | VAF 113/350 reads (32%) | catalogued as rs773241669; called by pindel, varscan2
- ADIPOR2 | c.587_590del p.S196Ffs*30 | Frame Shift Del (DEL) | VAF 44/294 reads (15%) | called by pindel, varscan2
- ATRX | c.4040_4041del p.V1347Efs*2 | Frame Shift Del (DEL) | VAF 320/550 reads (58%) | called by pindel, varscan2
- B4GALT5 | c.998_1000del p.G333del | In Frame Del (DEL) | VAF 174/482 reads (36%) | called by pindel, varscan2
- C9orf43 | c.509C>A p.S170Y | Missense Mutation (SNP) | VAF 16/476 reads (3%) | SIFT tolerated (0.94); PolyPhen benign (0.021); called by muse, mutect2
- CACNA1B | c.6268C>A p.P2090T | Missense Mutation (SNP) | VAF 45/301 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- CDKN1B | c.151_152del p.D51Hfs*73 | Frame Shift Del (DEL) | VAF 66/217 reads (30%) | called by pindel, varscan2
- COCH | c.76G>A p.G26R | Missense Mutation (SNP) | VAF 14/428 reads (3%) | SIFT deleterious, low confidence (0); called by muse, mutect2
- DUSP6 | c.914_915del p.V305Gfs*16 | Frame Shift Del (DEL) | VAF 153/360 reads (43%) | called by pindel, varscan2
- DYNC2H1 | c.3573+2T>G p.X1191_splice | Splice Site (SNP) | VAF 35/250 reads (14%) | called by muse, mutect2, varscan2
- FKBP15 | c.628C>A p.Q210K | Missense Mutation (SNP) | VAF 200/485 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- GPR137B | c.578_579del p.V193Afs*5 | Frame Shift Del (DEL) | VAF 72/450 reads (16%) | called by pindel, varscan2
- H3-3B | c.346_347del p.K116Efs*31 | Frame Shift Del (DEL) | VAF 69/433 reads (16%) | called by mutect2, pindel, varscan2
- IL10RA | c.971C>G p.T324S | Missense Mutation (SNP) | VAF 10/226 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.015); called by muse, mutect2
- INPPL1 | c.1789_1790del p.L597Afs*32 | Frame Shift Del (DEL) | VAF 37/364 reads (10%) | called by pindel, varscan2
- JMJD1C | c.1268_1270del p.G423del | In Frame Del (DEL) | VAF 66/302 reads (22%) | called by mutect2, pindel, varscan2
- MAOA | c.481A>T p.I161F | Missense Mutation (SNP) | VAF 58/264 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- NAXD | c.940A>G p.T314A | Missense Mutation (SNP) | VAF 40/387 reads (10%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.027); called by muse, mutect2
- NUP98 | c.734C>A p.T245N | Missense Mutation (SNP) | VAF 12/422 reads (3%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.893); called by muse, mutect2
- PCDH15 | c.4987A>T p.K1663* (on ENST00000644397 / NM_001354429.2; = p.K1605* on NM_001142771.2) | Nonsense Mutation (SNP) | VAF 20/316 reads (6%) | called by muse, mutect2
- PTEN | c.1024_1026del p.K342del | In Frame Del (DEL) | VAF 63/214 reads (29%) | called by mutect2, pindel, varscan2
- PTPRZ1 | c.1856_1857del p.Y619* | Frame Shift Del (DEL) | VAF 44/242 reads (18%) | called by pindel, varscan2
- RB1 | c.1887_1888del p.E629Dfs*23 | Frame Shift Del (DEL) | VAF 208/386 reads (54%) | called by pindel, varscan2
- SLCO2B1 | c.650_651del p.F217Cfs*39 | Frame Shift Del (DEL) | VAF 64/349 reads (18%) | called by mutect2, pindel, varscan2
- SLITRK2 | c.1816C>A p.P606T | Missense Mutation (SNP) | VAF 14/354 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0.288); called by muse, mutect2
- SPATA31D1 | c.2479G>T p.E827* | Nonsense Mutation (SNP) | VAF 67/502 reads (13%) | called by muse, mutect2, varscan2
- VAMP7 | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 92/725 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- ZNF677 | c.697G>C p.V233L | Missense Mutation (SNP) | VAF 28/558 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.104); called by muse, mutect2
- CD70 | c.426G>A p.L142= | Silent (SNP) | VAF 30/472 reads (6%) | catalogued as rs368645120; called by muse, mutect2
- LAMA1 | c.6849C>G p.G2283= | Silent (SNP) | VAF 170/574 reads (30%) | called by muse, mutect2, varscan2
- NDST3 | c.1371A>T p.P457= | Silent (SNP) | VAF 89/419 reads (21%) | called by muse, mutect2, varscan2
- OR14I1 | c.723C>T p.P241= | Silent (SNP) | VAF 96/457 reads (21%) | catalogued as COSV100700542; called by muse, mutect2, varscan2
- OSBPL5 | c.69C>G p.V23= | Silent (SNP) | VAF 83/367 reads (23%) | called by muse, mutect2, varscan2
- HHAT | c.*18C>T | 3'UTR (SNP) | VAF 10/250 reads (4%) | catalogued as rs775939647; called by muse, mutect2
- KLRK1 | c.*11C>A | 3'UTR (SNP) | VAF 58/247 reads (23%) | catalogued as rs987077817, COSV99554951; called by muse, mutect2, varscan2
- MIR9-1HG | n.457-73_457-70del | Intron (DEL) | VAF 13/74 reads (18%) | called by mutect2, pindel, varscan2
- PGBD2 | c.-11C>T | 5'UTR (SNP) | VAF 50/233 reads (21%) | catalogued as rs912148337; called by muse, mutect2, varscan2
- PLIN1 | c.*52_*53del | 3'UTR (DEL) | VAF 37/191 reads (19%) | called by mutect2, pindel, varscan2
- PPP1R9B | c.*26T>C | 3'UTR (SNP) | VAF 9/155 reads (6%) | called by muse, mutect2
- RIT2 | c.-28_-26del | 5'UTR (DEL) | VAF 22/90 reads (24%) | catalogued as rs753131696; called by pindel, varscan2
- RPL9 | c.162+15_162+17del | Intron (DEL) | VAF 21/119 reads (18%) | called by pindel, varscan2
- SIGLEC12 | c.428-26C>T | Intron (SNP) | VAF 100/862 reads (12%) | catalogued as COSV99388990; called by muse, mutect2, varscan2
- ZSCAN5A | c.*64A>G | 3'UTR (SNP) | VAF 13/120 reads (11%) | called by muse, mutect2
